Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4323, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4323-01A (Primary Tumor).

PART 1: HIGHEST LYMPH NODE, RIGHT HEMICOLECTOMY –
ONE (1) LYMPH NODE NEGATIVE FOR MALIGNANCY.

PART 2: RIGHT COLON AND PORTION OF TERMINAL ILEUM, HEMICOLECTOMY –

- A. POORLY DIFFERENTIATED CARCINOMA OF CECUM, EXTENDING THROUGH MUSCULAR WALL AND SEROSAL ADIPOSE TISSUE TO REACH THE PERITONEAL SURFACE (see comment).
- B. SURGICAL MARGINS FREE OF TUMOR.
- C. FIVE/THIRTY (5/30) LYMPH NODE POSITIVE FOR MALIGNANCY.
- D. POSITIVE VASCULAR INVASION BY TUMOR.
- E. pT4, N2, M1, DUKES' 3, ASTLER-COLLER GRADE: 6.
- F. DIFFUSE QUIESCENT COLITIS WITH MILD ATROPHY IN KEEPING WITH ULCERATIVE COLITIS (see comment).
- G. ONE (1) PSEUDOPOLYP SHOWING ULCERATION AND ACUTE AND CHRONIC INFLAMMATION.
- H. APPENDIX WITH NO SIGNIFICANT PATHOLOGIC CHANGE.

PART 3: LIVER, BIOPSY –

METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA.

- A. Location: 1
- 1. Ileocecal Region
- 2. Ascending Colon
- 3. Transverse Colon
- 4. Descending Colon
- 5. Sigmoid Colon
- 6. Rectum
- B. Procedure: 1
- 1. Segmental Colectomy
- 2. Total Colectomy
- 3. Other
- C. Size of Tumor (maximum dimension): 4.0 cm
- D. Type: 1
- 1. Adenocarcinoma, NOS
- 2. Adenocarcinoma arising in a background of an adenoma.
- 3. Adenocarcinoma arising in a background of inflammatory bowel disease
- 4. Adenosquamous carcinoma
- 5. Carcinoid Tumor (Neuroendocrine Tumor)
- 6. Mucinous Adenocarcinoma
- 7. Signet ring cell type Adenocarcinoma
- 8. Neuroendocrine Carcinoma
- 9. Squamous Cell Carcinoma
- 10. Undifferentiated Carcinoma
- 11. Sarcoma
- 12. Smooth Muscle Tumor
- 13. Gastrointestinal stromal tumor
- 14. Lymphoma
- 15. Other
- E. Grade: 3
- 1. Well differentiated
- 2. Moderately differentiated
- 3. Poorly differentiated
- F. Extent of Infiltration: 5
- 1. Limited to the mucosa
- 2. Into submucosa
- 3. Involving muscularis propria
- 4. Infiltrating through muscularis propria into serosal adipose tissue
- 5. Involving adjacent organs/ pelvic wall
- G. Angiolymphatic Invasion: 1
- 1. Yes
- 2. No
- H. Surgical Margins Involved: 2
- 1. Yes
- 2. No
- I. Number of positive lymph nodes: 5
- J. Total number of lymph nodes examined: 30
- K. Extracapsular spread : 2
- 1. Yes
- 2. No.
- L. Associated conditions: 1
- 1. Ulcerative colitis.
- 2. Crohn's Disease.
- 3. History/ presence of adenomatous polyps.
- 4. Multiple polyposis syndromes.
- 5. Diverticulosis.
- M. TNM Stage: T 4 N 2 M 1
- N. Dukes' Stage: 3
- 1. A (limited to mucosa and muscularis)
- 2. B (through muscularis into subserosa)
- 3. C (affecting lymph nodes)
- 4. D (metastatic)
- O. Astler-Coller Stage: 6
- 1. A (mucosa but not into muscularis propria)
- 2. B1 (muscularis propria but not through to subserosa)
- 3. B2 (through muscularis propria into subserosal fibroadipose tissue, LN negative)
- 4. C1 (limited to muscularis propria but not through subserosa, LN positive)
- 5. C2 (invades serosal adipose tissue. LN positive)
- 6. D (metastatic disease)

Source: NCI Genomic Data Commons file 1e064cf7-9be6-43bb-b14d-4421b9f4d70e (TCGA-AZ-4323.0CCFD95B-A393-4C2A-90BB-F563EEC83E9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).